Surgical pathology report (de-identified scan), TCGA case TCGA-28-2502, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-2502-01B (Primary Tumor).

TCGA-28-2502

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

DIAGNOSIS:

A. BRAIN, RIGHT FRONTAL, BIOPSY:

- Glioblastoma multiforme, WHO grade IV

B. BRAIN, RIGHT FRONTAL, NCI#1, BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Tumor cellularity 10%
- 0% of tumor necrosis

C. BRAIN, RIGHT FRONTAL, NCI#2, BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- 70% of tumor cellularity
- 0% of tumor necrosis

D. BRAIN, RIGHT FRONTAL, NCI#3, BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- 60% of tumor cellularity
- 0% of tumor necrosis

E. BRAIN, RIGHT FRONTAL, NCI#4, BIOPSY:

- Gray and white matter with ependymal lining and scattered atypical cells
- Less than 2% of tumor cellularity
- 0% of tumor necrosis

F. BRAIN, RIGHT FRONTAL, NCI#5, BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- 95% of tumor cellularity
- 20% of tumor necrosis

G. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

H. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

IDC2a: Selected slides were reviewed in consultation with

COMMENT:

Source: NCI Genomic Data Commons file ab8892bb-f7a4-4e16-abe0-7ff848062635 (TCGA-28-2502.960254B4-0BA4-417A-A2BC-6C334061B774.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).